Somatic mutation profile of tumor specimen C3L-02705-71 (aliquot CPT0189650007) from CPTAC case C3L-02705, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.3 years (22,025 days).
Specimen C3L-02705-71: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2bc0e28-d785-4f9f-960f-713bf09f19a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02705-31 (Blood Derived Normal), aliquot CPT0190640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da8a81ec-e659-4c7d-a250-94bffa5a8164

The open-access MAF lists 69 somatic variants for this specimen: 45 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 17, Frame Shift Del 4, 3'UTR 2, Intron 2, Nonsense Mutation 1, 5'Flank 1, RNA 1, Splice Region 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs397514560, CM1212354, COSV64293891, COSV64295025, COSV64300549; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALPK1 | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs147228808; called by muse, mutect2, varscan2
- CLEC5A | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1487774670, COSV69397332; called by muse, mutect2
- GBP6 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as rs369820127; called by muse, mutect2, varscan2
- GPR139 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 75/378 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746326530, COSV58503678; called by muse, mutect2, varscan2
- GPS1 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs754427804, COSV100136159; called by muse, mutect2, varscan2
- HECW2 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs762187660, COSV99645916; called by muse, mutect2, varscan2
- KSR2 | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1422658754, COSV56669310; called by muse, mutect2, varscan2
- LILRA2 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1468362738; called by muse, varscan2
- LLGL2 | c.1963C>A p.R655S | Missense Mutation (SNP) | VAF 90/487 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149923284; called by muse, mutect2, varscan2
- MGAM2 | c.4661C>A p.T1554N | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs1282523573, COSV72176253; called by muse, mutect2
- MMP12 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs570000197, COSV58258950; called by muse, mutect2, varscan2
- MUC16 | c.43442G>A p.R14481Q | Missense Mutation (SNP) | VAF 19/287 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.257); catalogued as rs368448305, COSV66695547; called by muse, mutect2
- OLIG2 | c.690_713del p.A231_V238del | In Frame Del (DEL) | VAF 117/648 reads (18%) | catalogued as rs1284605046; called by mutect2, pindel, varscan2
- OR2A2 | c.363G>T p.R121S | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs959961776; called by muse, mutect2
- RYR2 | c.5198C>T p.T1733M | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs750668049, COSV63674312; called by muse, mutect2, varscan2
- SCN9A | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201071819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNAP91 | c.46A>G p.S16G | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs374341222; called by muse, mutect2, varscan2
- TGFA | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 90/417 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs138392270; called by muse, mutect2, varscan2
- TSPAN4 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs371055480; called by muse, mutect2, varscan2
- WNT11 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 111/424 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs200871564; called by muse, mutect2, varscan2
- ZNF235 | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs147781913; called by muse, mutect2, varscan2
- ADAMTS18 | c.3326C>G p.T1109S | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2
- ADCY3 | c.2569del p.S857Pfs*4 | Frame Shift Del (DEL) | VAF 80/424 reads (19%) | called by pindel, varscan2
- ADGRL1 | c.563_566del p.T188Sfs*104 (on ENST00000340736 / NM_001008701.3; = p.T183Sfs*104 on NM_014921.5) | Frame Shift Del (DEL) | VAF 52/303 reads (17%) | called by pindel, varscan2
- ANKRD30B | c.1324A>G p.T442A | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- CDCA5 | c.583del p.M196Cfs*64 | Frame Shift Del (DEL) | VAF 47/238 reads (20%) | called by mutect2, pindel, varscan2
- CHIA | c.631A>G p.T211A (on ENST00000343320; = p.T103A on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRB2 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KLRD1 | c.101-8T>C | Splice Region (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2, varscan2
- KRT34 | c.703A>G p.N235D | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- LRP1B | c.8521G>T p.G2841* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | called by mutect2, varscan2
- MUC16 | c.41968A>T p.T13990S | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- NCOA6 | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLGN4X | c.1403A>G p.Y468C | Missense Mutation (SNP) | VAF 35/464 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR4A5 | c.724A>G p.T242A | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.12); called by muse, mutect2
- PGA5 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 118/513 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, varscan2
- PIWIL4 | c.2483A>T p.K828M | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PSME4 | c.4592C>T p.P1531L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBMY1A1 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by mutect2, varscan2
- RIMBP3 | c.2870C>T p.A957V | Missense Mutation (SNP) | VAF 72/1092 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.273); called by muse, mutect2
- RNF19A | c.2088_2090delinsA p.L697Vfs*10 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | called by pindel, varscan2*
- TPTE | c.1489T>C p.W497R (on ENST00000618007 / NM_199261.4; = p.W479R on NM_199259.4) | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTN | c.99737C>G p.P33246R (on ENST00000591111; = p.P25822R on NM_003319.4) | Missense Mutation (SNP) | VAF 59/242 reads (24%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF254 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 70/382 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ADAMTS2 | c.648C>T p.P216= | Silent (SNP) | VAF 63/312 reads (20%) | called by muse, mutect2, varscan2
- CAVIN4 | c.456C>T p.N152= | Silent (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- CHCHD2 | c.228G>A p.L76= | Silent (SNP) | VAF 2278/2720 reads (84%) | called by muse, mutect2, varscan2
- COL6A5 | c.5589C>T p.N1863= (on ENST00000312481; = p.N1859= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/380 reads (22%) | catalogued as rs955469374, COSV55202357; called by muse, mutect2, varscan2
- CPQ | c.549G>A p.T183= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs201427497; called by muse, mutect2, varscan2
- DLGAP4 | c.903C>T p.H301= | Silent (SNP) | VAF 120/602 reads (20%) | catalogued as rs370088930; called by muse, varscan2
- ENPP3 | c.798C>T p.A266= | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as rs200254628; called by muse, mutect2, varscan2
- GBP2 | c.1027C>T p.L343= | Silent (SNP) | VAF 126/602 reads (21%) | called by muse, mutect2, varscan2
- HLA-DMA | c.213C>T p.F71= | Silent (SNP) | VAF 45/512 reads (9%) | catalogued as rs12153970; called by muse, mutect2
- KIF21A | c.621G>A p.L207= | Silent (SNP) | VAF 46/217 reads (21%) | catalogued as COSV100735392; called by muse, mutect2, varscan2
- LRRTM1 | c.1062G>A p.L354= | Silent (SNP) | VAF 14/326 reads (4%) | catalogued as COSV54445145; called by muse, mutect2
- MUC16 | c.33663G>A p.A11221= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as rs373172082; called by muse, mutect2, varscan2
- NCOA6 | c.903A>T p.G301= | Silent (SNP) | VAF 105/476 reads (22%) | called by muse, mutect2, varscan2
- NDUFB4 | c.321T>G p.T107= | Silent (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- OR5A2 | c.444C>T p.G148= | Silent (SNP) | VAF 40/207 reads (19%) | catalogued as rs141672631; called by muse, mutect2, varscan2
- OXER1 | c.690C>T p.S230= | Silent (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- THBS2 | c.1893C>T p.P631= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as rs748776522, COSV100828074; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504607 del TTTG | 5'Flank (DEL) | VAF 22/124 reads (18%) | called by mutect2, pindel, varscan2
- FOLH1B | n.808T>C | RNA (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- IGSF22 | c.*831C>T | 3'UTR (SNP) | VAF 56/224 reads (25%) | called by muse, mutect2, varscan2
- MAP3K7CL | c.371-15800C>T | Intron (SNP) | VAF 49/189 reads (26%) | catalogued as rs1258394878; called by muse, mutect2, varscan2
- PTPN22 | c.*71T>A | 3'UTR (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- TPRX1 | c.-18C>T | 5'UTR (SNP) | VAF 20/102 reads (20%) | called by mutect2, varscan2
- ZNF720 | c.361+1799C>T | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100335710; called by muse, mutect2
